Gene-level copy-number profile of tumor specimen TCGA-02-0333-01A from TCGA case TCGA-02-0333, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 77.9 years (28,449 days).
Specimen TCGA-02-0333-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.53c9bd8f-d048-4e07-8beb-8741f82f4587.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 5,128 have no estimate.
https://portal.gdc.cancer.gov/files/517e13ac-3a39-4a73-816c-110bcbe2c003

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 109; copy number 1: 4,996; copy number 2: 46,614; copy number 3: 3,775; copy number 4: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-02-0333-01): tumor purity 0.93, ploidy 1.97, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 109 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:48,532,854–50,023,954, 1 gene (within-gene range 0–1): AGBL4.
- chr1:48,727,519–51,235,096, 32 genes (within-gene range 0–1): BEND5, AL645507.1, AC099788.1, AGBL4-AS1, AGBL4-IT1, AL390023.1, ZNF859P, AL645730.1, MTND2P29, ELAVL4, AL583843.1, ELAVL4-AS1, AL592182.1, LINC02808, AL592182.2, AL596275.1, HMGB1P45, FCF1P6, DMRTA2, AL049637.1, FAF1, FAF1-AS1, RNU6-1026P, PHBP12, MRPS6P2, CDKN2C, MIR4421, MIR6500, C1orf185, Y_RNA, CFL1P2, LINC01562.
- chr9:19,705,338–23,438,700, 76 genes (within-gene range 0–1) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 4,996. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
